Somatic mutation profile of tumor specimen TARGET-20-PATMFM-09A (aliquot TARGET-20-PATMFM-09A-01D) from TARGET case TARGET-20-PATMFM, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.2 years (5,190 days).
Specimen TARGET-20-PATMFM-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8b5c75b3-97cf-439c-9891-766ff618ed0b.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PATMFM-14A (Bone Marrow Normal), aliquot TARGET-20-PATMFM-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f57e5ddf-be4c-44eb-9bdb-110b807faad8

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 58/169 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs121913255, COSV54736320, COSV54736991, COSV54744813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- WT1 | c.1098_1105dup p.S369Lfs*71 | Frame Shift Ins (INS) | VAF 31/134 reads (23%) | catalogued as COSV60068039, COSV60068389, COSV60070959, COSV60083889; called by mutect2, varscan2
- ETS2 | c.*1576C>T | 3'UTR (SNP) | VAF 94/213 reads (44%) | catalogued as rs1015548268; called by muse, mutect2, varscan2
